Somatic mutation profile of tumor specimen 0DKPX0 from CCDI case PBBYKM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.3 years (3,400 days).
Specimen 0DKPX0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c572810a-a631-4353-a56d-518530c347f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKPWF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85e775bd-6da1-49a4-a783-75b999065125

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 803/1535 reads (52%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 1202/1339 reads (90%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALOX15B | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 469/1162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101205724, COSV66480335; called by muse, mutect2, varscan2
- CNTN6 | c.2465C>A p.S822* | Nonsense Mutation (SNP) | VAF 54/2230 reads (2%) | catalogued as rs1267226389, COSV63166022; called by muse, mutect2
- DSC1 | c.1924T>C p.Y642H | Missense Mutation (SNP) | VAF 356/1390 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1242177382; called by muse, mutect2, varscan2
- PDGFRA | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 9616/10381 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57266965; called by mutect2, varscan2
- SLC7A2 | c.1226C>T p.A409V (on ENST00000494857 / NM_001370338.1; = p.A448V on NM_003046.6) | Missense Mutation (SNP) | VAF 364/2084 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs763868224, COSV99134483; called by muse, mutect2, varscan2
- ZSCAN29 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 556/1198 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778677754, COSV53018169; called by muse, mutect2, varscan2
- BCL9L | c.2929del p.Q977Rfs*54 | Frame Shift Del (DEL) | VAF 99/640 reads (15%) | called by pindel, varscan2
- DENND2B | c.1834C>G p.R612G | Missense Mutation (SNP) | VAF 180/761 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- HJURP | c.445A>G p.K149E | Missense Mutation (SNP) | VAF 172/1622 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PARP4 | c.5104C>A p.Q1702K | Missense Mutation (SNP) | VAF 75/950 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.899); called by muse, mutect2
- PHF3 | c.5404C>A p.Q1802K | Missense Mutation (SNP) | VAF 116/2360 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2
- EPX | c.2106C>T p.S702= | Silent (SNP) | VAF 80/1957 reads (4%) | called by muse, mutect2
- FOXO3 | c.729C>T p.S243= | Silent (SNP) | VAF 135/590 reads (23%) | catalogued as rs753663231; called by mutect2, varscan2
- OLFML2A | c.306C>T p.N102= | Silent (SNP) | VAF 666/1316 reads (51%) | catalogued as rs752387534, COSV59161440; called by muse, mutect2, varscan2
- PPP5C | c.1135+81G>A | Intron (SNP) | VAF 49/184 reads (27%) | catalogued as rs756256296; called by muse, mutect2, varscan2
